Gene-level copy-number profile of tumor specimen TCGA-MI-A75G-01A from TCGA case TCGA-MI-A75G, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 63.7 years (23,284 days).
Specimen TCGA-MI-A75G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.6a3c9cc0-b684-4401-a82e-92ac58fb6bad.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-MI-A75G-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2202089f-efa8-4df3-999d-dc4c3b9670b7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 4,036; copy number 2: 33,021; copy number 3: 18,097; copy number 4: 2,536; copy number 5: 2,075; copy number 6: 10; copy number 7: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-MI-A75G-01A-11D-A32F-01): tumor purity 0.88, ploidy 2.37, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:16,137,768–16,192,151, 2 genes: RNU6-862P, RN7SL442P.
- chr17:46,193,576–46,757,464, 16 genes: KANSL1-AS1, Y_RNA, MAPK8IP1P1, AC005829.2, AC005829.1, ARL17B, LRRC37A, RN7SL656P, NSFP1, RDM1P2, LRRC37A2, ARL17A, RN7SL199P, FAM215B, NSF, RPS7P11.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,111 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,253,380–38,378,804, 22 genes, copy number 5 (within-gene range 3–5): TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRG-AS1, TRGV5P, TRGV5, TRGV4, TRGV3, TRGV2.
- chr7:78,017,055–148,503,458, 1,287 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr17:16,525,832–16,864,223, 26 genes, copy number 7: AC127540.2, ZNF287, AC127540.1, SRSF6P2, ZNF624, AC098850.2, NEK4P2, RNASEH1P2, CCDC144A, AC098850.3, RNU6-405P, RN7SL620P, UPF3AP1, USP32P1, SRP68P1, AC098850.4, AC098850.1, FAM106C, AC022596.1, NOS2P4, KRT16P6, KRT16P2, KRT17P1, KRT17P4, COTL1P1, AC022596.2.
- chr20:34,088,309–64,313,132, 776 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,121. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
